Somatic mutation profile of tumor specimen TARGET-30-PARETE-01A (aliquot TARGET-30-PARETE-01A-01D) from TARGET case TARGET-30-PARETE, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.9 years (686 days).
Specimen TARGET-30-PARETE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b55244e8-943c-433a-bd51-58c321da0451.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARETE-10A (Blood Derived Normal), aliquot TARGET-30-PARETE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce1905d3-3cde-46d1-86e7-768061c4d025

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FANCM | c.4951G>T p.E1651* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV57503751; called by muse, mutect2, varscan2
- HGFAC | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.088); catalogued as COSV58756021; called by muse, mutect2, varscan2
- LPA | c.3776T>C p.V1259A | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as rs770898075, COSV60309666; called by muse, mutect2, varscan2
- PLIN5 | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV67850985; called by muse, mutect2, varscan2
- RGR | c.425C>A p.S142Y | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.441); catalogued as COSV63895025; called by muse, mutect2, varscan2
- PRAMEF2 | c.*2G>T | 3'UTR (SNP) | VAF 7/28 reads (25%) | catalogued as rs758220459; called by mutect2, varscan2
